Somatic mutation profile of tumor specimen C3L-02211-01 (aliquot CPT0127860006) from CPTAC case C3L-02211, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.6 years (20,669 days).
Specimen C3L-02211-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7312f6d5-4c91-40ae-b770-b06618d0f4ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02211-31 (Blood Derived Normal), aliquot CPT0126630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d5ed61-f8f2-4376-b541-837ded45e508

The open-access MAF lists 72 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Frame Shift Del 5, Intron 5, 5'UTR 3, 3'UTR 3, Frame Shift Ins 2, In Frame Del 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBWD3 | c.982_984del p.Q328del | In Frame Del (DEL) | VAF 56/538 reads (10%) | catalogued as rs1554669885; called by pindel, varscan2
- EP300 | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 121/558 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs548993665; called by muse, mutect2, varscan2
- FADS3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV53877717; called by muse, mutect2, varscan2
- IRS4 | c.2672G>T p.R891L | Missense Mutation (SNP) | VAF 130/589 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV64532693; called by muse, mutect2, varscan2
- LGALS12 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 112/553 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV55369589; called by muse, mutect2, varscan2
- NCAM1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100378387; called by muse, mutect2, varscan2
- NOP2 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1250496977; called by muse, mutect2, varscan2
- PIGB | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179198642, COSV51241309; called by muse, mutect2, varscan2
- PKD1L3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs559511879; called by muse, mutect2, varscan2
- PRRC2A | c.6452C>G p.P2151R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52993224; called by muse, mutect2, varscan2
- SLITRK2 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59425040; called by muse, mutect2, varscan2
- VHL | c.470del p.T157Ifs*2 | Frame Shift Del (DEL) | VAF 102/451 reads (23%) | catalogued as CM951289, COSV56549496, COSV56562341; called by mutect2, pindel, varscan2
- ZNF780B | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV55466136; called by muse, mutect2, varscan2
- AL121899.2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- ALCAM | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- CARD14 | c.2453_2463del p.L818Pfs*31 | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | called by mutect2, pindel, varscan2
- COG7 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 105/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.4540G>A p.A1514T | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A2 | c.1676A>T p.D559V | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CTSK | c.703del p.L235* | Frame Shift Del (DEL) | VAF 70/350 reads (20%) | called by mutect2, pindel, varscan2
- DPP4 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM221A | c.392_406del p.D131_A135del | In Frame Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel
- FASTKD5 | c.1858C>A p.H620N | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FN1 | c.4922C>A p.T1641N | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC2 | c.9226G>A p.D3076N | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-66 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- INSR | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LGI2 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.515); called by muse, varscan2
- LRIG3 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 15/501 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- MED23 | c.585dup p.L196Tfs*31 | Frame Shift Ins (INS) | VAF 46/245 reads (19%) | called by mutect2, pindel, varscan2
- MEN1 | c.716T>A p.M239K | Missense Mutation (SNP) | VAF 83/434 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MUC2 | c.4033C>T p.H1345Y | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.1548_1549dup p.M517Rfs*12 | Frame Shift Ins (INS) | VAF 97/483 reads (20%) | called by mutect2, pindel, varscan2
- NEO1 | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLD5 | c.1061G>A p.S354N (on ENST00000442594; = p.S292N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2
- PTCHD4 | c.1454T>G p.I485S | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RCAN2 | c.473del p.P158Qfs*12 | Frame Shift Del (DEL) | VAF 44/240 reads (18%) | called by mutect2, pindel, varscan2
- SACS | c.4770del p.K1590Nfs*33 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, varscan2
- SAMHD1 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 100/518 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SEH1L | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- STAMBP | c.204-5C>A | Splice Region (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- TICAM1 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.184); called by muse, varscan2
- TTLL7 | c.2272G>A p.V758I | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VWCE | c.582T>G p.C194W | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZC3H7A | c.2825T>G p.M942R | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- A1BG | c.570C>T p.G190= | Silent (SNP) | VAF 87/333 reads (26%) | catalogued as rs138577019; called by muse, mutect2, varscan2
- COG7 | c.384A>G p.A128= | Silent (SNP) | VAF 104/482 reads (22%) | called by muse, mutect2, varscan2
- DST | c.16002C>A p.P5334= (on ENST00000361203 / NM_001374722.1; = p.P2922= on NM_015548.5) | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV99760825; called by muse, mutect2, varscan2
- FOXL2NB | c.484C>T p.L162= | Silent (SNP) | VAF 155/777 reads (20%) | called by muse, mutect2, varscan2
- GABRB2 | c.444C>T p.V148= | Silent (SNP) | VAF 91/459 reads (20%) | catalogued as rs771899561; called by muse, mutect2, varscan2
- HECW1 | c.4800C>G p.T1600= | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- HNF4G | c.1029T>C p.H343= (on ENST00000354370 / NM_001330561.2; = p.H390= on NM_004133.5) | Silent (SNP) | VAF 51/249 reads (20%) | catalogued as COSV62974885; called by muse, mutect2, varscan2
- MFSD10 | c.646C>T p.L216= | Silent (SNP) | VAF 102/466 reads (22%) | called by muse, mutect2, varscan2
- MUC20 | c.1422C>A p.V474= | Silent (SNP) | VAF 71/587 reads (12%) | catalogued as COSV100291392, COSV100291415; called by muse, mutect2, varscan2
- NRP2 | c.234C>T p.I78= | Silent (SNP) | VAF 26/453 reads (6%) | catalogued as rs1435124991, COSV55930294; called by muse, mutect2
- NTNG1 | c.795G>A p.R265= | Silent (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- RIN1 | c.333C>A p.A111= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- SLFN5 | c.2448G>T p.L816= | Silent (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- URGCP | c.1764G>T p.T588= (on ENST00000453200 / NM_001077663.3; = p.T579= on NM_017920.4) | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV56248471; called by muse, mutect2, varscan2
- VNN3 | c.666G>C p.V222= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4050G>C | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as rs781960872, COSV61448686; called by muse, varscan2
- CFB | c.*38A>G | 3'UTR (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- CTSE | c.-13G>A | 5'UTR (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- DOK7 | chr4:3496842 G>C | 3'Flank (SNP) | VAF 63/275 reads (23%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2182G>A | 3'UTR (SNP) | VAF 59/282 reads (21%) | called by muse, mutect2, varscan2
- LEAP2 | c.*92_*93dup | 3'UTR (INS) | VAF 58/336 reads (17%) | called by mutect2, pindel, varscan2
- MDH2 | c.-22C>T | 5'UTR (SNP) | VAF 103/536 reads (19%) | catalogued as rs377064742, COSV99951651; called by muse, mutect2, varscan2
- NDUFS4 | c.177+1265T>C | Intron (SNP) | VAF 63/266 reads (24%) | catalogued as rs1284056448; called by muse, mutect2, varscan2
- SPANXN1 | c.-34G>T | 5'UTR (SNP) | VAF 18/380 reads (5%) | called by muse, mutect2
- TECTB | c.941-23C>G | Intron (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- TTLL11 | c.1539+11C>G | Intron (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.34265-4896G>A | Intron (SNP) | VAF 76/396 reads (19%) | called by muse, mutect2
